Somatic mutation profile of tumor specimen TCGA-C5-A7CM-01A (aliquot TCGA-C5-A7CM-01A-11D-A33O-09) from TCGA case TCGA-C5-A7CM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 35.2 years (12,853 days).
Specimen TCGA-C5-A7CM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 439e9300-5f93-4bac-97ad-0f410049b9ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7CM-10A (Blood Derived Normal), aliquot TCGA-C5-A7CM-10A-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a2ff26a-07c4-4ab2-8dac-09db7b66ca57

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.3289A>T p.N1097Y | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV55594976; called by muse, mutect2, varscan2
- ABL1 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59335353; called by muse, mutect2, varscan2
- ARMC9 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998531981, COSV63022157; called by muse, mutect2, varscan2
- CAPSL | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs200635899; called by muse, mutect2, varscan2
- CYB561D1 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV60205277; called by muse, mutect2, varscan2
- DIMT1 | c.688A>C p.T230P | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV52234059; called by muse, mutect2, varscan2
- FBXW10 | c.2574C>A p.F858L | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57060354; called by muse, mutect2, varscan2
- GNL1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV64921218; called by muse, mutect2, varscan2
- LRCH2 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1556544155, COSV57745940; called by muse, mutect2, varscan2
- PAGE4 | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54334867; called by muse, mutect2, varscan2
- PLSCR5 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71649113; called by muse, mutect2, varscan2
- WBP1 | c.551dup p.H185Sfs*5 | Frame Shift Ins (INS) | VAF 25/98 reads (26%) | catalogued as rs547055147; called by mutect2, varscan2
- CCR4 | c.12G>A p.T4= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs763338260, COSV58382709, COSV58384303; called by muse, mutect2, varscan2
- CD14 | c.726C>T p.A242= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV57371022; called by muse, mutect2, varscan2
- ORAI3 | c.420C>T p.H140= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1428700046, COSV52689736; called by muse, mutect2, varscan2
- TBX22 | c.21G>A p.A7= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV64784970, COSV64786267; called by muse, mutect2, varscan2
